Somatic mutation profile of tumor specimen TCGA-23-1032-01A (aliquot TCGA-23-1032-01A-02W-0486-08) from TCGA case TCGA-23-1032, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 73.1 years (26,715 days).
Specimen TCGA-23-1032-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2033843-b877-45a6-ba24-81518d8e14d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1032-10A (Blood Derived Normal), aliquot TCGA-23-1032-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b0d72ad-3168-4f5f-9009-6eb0df691d23

The open-access MAF lists 141 somatic variants for this specimen: 97 protein-altering or splice-affecting, 37 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 37, Nonsense Mutation 4, Frame Shift Ins 4, Splice Site 3, RNA 3, Intron 2, Frame Shift Del 1, 3'UTR 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 656/757 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.4717C>T p.H1573Y (on ENST00000272895 / NM_173076.3; = p.H1255Y on NM_015657.3) | Missense Mutation (SNP) | VAF 123/243 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV55960458; called by muse, mutect2, varscan2
- AFM | c.361A>G p.R121G | Missense Mutation (SNP) | VAF 73/121 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56920282; called by muse, mutect2, varscan2
- ALDH1A2 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV99991128; called by mutect2, varscan2
- ANGPTL6 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 28/642 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as rs369036998; called by muse, mutect2
- ANKRD30A | c.1148T>A p.I383N (on ENST00000611781; = p.I327N on NM_052997.2) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV64611083; called by muse, mutect2, varscan2
- AP2A1 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as rs1443220381; called by muse, mutect2, varscan2
- ARHGEF15 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100730179; called by muse, mutect2
- ARID4B | c.2805G>A p.W935* | Nonsense Mutation (SNP) | VAF 176/334 reads (53%) | catalogued as COSV51603729; called by mutect2, varscan2
- BAG5 | c.80T>G p.V27G | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54571185; called by muse, mutect2, varscan2
- BMP15 | c.629A>T p.Q210L | Missense Mutation (SNP) | VAF 70/616 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.115); catalogued as COSV53140578; called by muse, mutect2, varscan2
- CASKIN1 | c.1097C>T p.S366L | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs549109076, COSV58872894; called by muse, mutect2, varscan2
- CDH4 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 80/226 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1358913423, COSV64655814; called by muse, mutect2, varscan2
- CEP131 | c.2872C>G p.L958V (on ENST00000269392 / NM_001319228.2; = p.L955V on NM_014984.4) | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.08); PolyPhen benign (0.108); catalogued as COSV53953314; called by muse, mutect2
- CLDN17 | c.500T>G p.L167R | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54523112; called by muse, mutect2, varscan2
- CLTC | c.3866A>G p.Y1289C | Missense Mutation (SNP) | VAF 231/273 reads (85%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs771160032, COSV52248008; called by muse, mutect2, varscan2
- CNIH4 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64795925; called by muse, varscan2
- CRYBA2 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV55387896, COSV99838153; called by muse, mutect2, varscan2
- DACH2 | c.1577A>T p.K526M | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64169738; called by muse, mutect2, varscan2
- DEPDC5 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 148/181 reads (82%) | catalogued as COSV56698334; called by muse, varscan2
- DGAT2L6 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100284011; called by muse, mutect2
- DIAPH2 | c.2837A>T p.K946M | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61270835; called by muse, mutect2, varscan2
- DLG5 | c.1619T>G p.I540S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64948192; called by muse, varscan2
- DTNB | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs200296831, COSV56477313; called by muse, mutect2, varscan2
- EFCAB6 | c.2558C>G p.S853C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53064089, COSV53074620; called by muse, mutect2, varscan2
- ENTR1 | c.362G>A p.G121D (on ENST00000357365 / NM_001039707.2; = p.G98D on NM_006643.4) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.394); catalogued as COSV100048410; called by muse, mutect2, varscan2
- ETV3L | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs771203484; called by muse, mutect2
- FOCAD | c.2212C>G p.P738A | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV58099443, COSV58099713; called by muse, mutect2, varscan2
- FUT2 | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.175); catalogued as rs1371097739; called by muse, mutect2
- GALNT18 | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 236/690 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99925957; called by muse, mutect2, varscan2
- GALNT2 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 41/272 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV100795920; called by muse, mutect2, varscan2
- GPC5 | c.1094A>G p.E365G | Missense Mutation (SNP) | VAF 101/161 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV65600848; called by muse, mutect2, varscan2
- GPR156 | c.934-1G>A p.X312_splice | Splice Site (SNP) | VAF 101/223 reads (45%) | catalogued as COSV59940071; called by muse, mutect2, varscan2
- GPRC6A | c.296T>A p.I99N | Missense Mutation (SNP) | VAF 50/57 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV59953231; called by muse, mutect2, varscan2
- GRHL3 | c.541G>A p.E181K (on ENST00000350501 / NM_198174.3; = p.E186K on NM_021180.3) | Missense Mutation (SNP) | VAF 17/254 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.551); catalogued as COSV52566002; called by muse, mutect2
- GRWD1 | c.1336G>A p.V446I | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); catalogued as rs371830640; called by muse, mutect2, varscan2
- H4-16 | c.193A>G p.N65D | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV100797690; called by muse, mutect2
- HMGB1 | c.296+1G>A p.X99_splice | Splice Site (SNP) | VAF 29/97 reads (30%) | catalogued as COSV58104046; called by muse, mutect2, varscan2
- HOXA11 | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs200850004, COSV50053188; called by muse, mutect2, varscan2
- IDO2 | c.363C>A p.N121K (on ENST00000389060; = p.N134K on NM_194294.2) | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs1436259384, COSV58425684; called by muse, mutect2, varscan2
- IFNL2 | c.200C>G p.S67W | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV59593502; called by muse, mutect2, varscan2
- IGSF10 | c.4142C>T p.T1381I | Missense Mutation (SNP) | VAF 68/385 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV56785825; called by muse, mutect2, varscan2
- ITIH5 | c.1594G>C p.A532P | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs529874492, COSV53666803, COSV53667075; called by muse, mutect2, varscan2
- ITPRIP | c.651dup p.E218Rfs*138 | Frame Shift Ins (INS) | VAF 10/97 reads (10%) | catalogued as rs765312007; called by pindel, varscan2
- KDM6B | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99642378; called by muse, mutect2, varscan2
- KLHL11 | c.2057G>A p.R686K | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.079); catalogued as COSV59862089; called by muse, mutect2, varscan2
- KSR2 | c.2420T>C p.F807S | Missense Mutation (SNP) | VAF 56/414 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD1311387; called by mutect2, varscan2
- LAMP1 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100208783; called by muse, varscan2
- LOXL4 | c.1531G>C p.G511R | Missense Mutation (SNP) | VAF 48/61 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV53256872; called by muse, mutect2, varscan2
- LPXN | c.676A>G p.M226V | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as rs1297602485, COSV67717198; called by muse, mutect2, varscan2
- LRRK2 | c.3456T>A p.C1152* | Nonsense Mutation (SNP) | VAF 54/368 reads (15%) | catalogued as COSV100108867, COSV54154569; called by mutect2, varscan2
- MKRN3 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV58810033; called by muse, mutect2, varscan2
- MPP3 | c.21C>G p.D7E | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.57); PolyPhen benign (0.108); catalogued as COSV68198262; called by muse, mutect2, varscan2
- MTMR8 | c.427A>T p.N143Y | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66393992; called by muse, mutect2, varscan2
- MTUS2 | c.449G>T p.R150M | Missense Mutation (SNP) | VAF 244/620 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV70916980; called by mutect2, varscan2
- NGFR | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 279/304 reads (92%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV50802354, COSV50805098; called by muse, mutect2, varscan2
- OR10A7 | c.322G>C p.G108R | Missense Mutation (SNP) | VAF 40/533 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100406636; called by muse, mutect2
- P4HB | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as rs771212950, COSV100515934; called by muse, mutect2
- PAX8 | c.1049C>A p.S350Y | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as COSV54506969, COSV99640145; called by muse, mutect2
- PCLO | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.025); catalogued as rs1161437707, COSV61624558; called by muse, mutect2
- PPP1R3A | c.1739A>T p.D580V | Missense Mutation (SNP) | VAF 164/917 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.518); catalogued as COSV52883499, COSV52893683; called by mutect2, varscan2
- PRAMEF4 | c.1096G>C p.D366H | Missense Mutation (SNP) | VAF 306/1492 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761366667, COSV52438708; called by muse, varscan2
- PTGIS | c.1025-1G>A p.X342_splice | Splice Site (SNP) | VAF 39/246 reads (16%) | catalogued as COSV54837178; called by mutect2, varscan2
- RAPH1 | c.1779C>A p.A593= | Splice Region (SNP) | VAF 6/16 reads (38%) | catalogued as COSV55584336; called by muse, mutect2, varscan2
- RASAL1 | c.1924G>A p.D642N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV55656292; called by muse, mutect2, varscan2
- RASL11B | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99954543; called by muse, mutect2
- RGS4 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 221/969 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as rs779741194, COSV63357460; called by mutect2, varscan2
- ROBO2 | c.2918T>A p.I973N | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59913083; called by muse, mutect2, varscan2
- RPS9 | c.514C>A p.R172S | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as COSV57190031; called by muse, mutect2, varscan2
- SHMT1 | c.1423T>G p.F475V | Missense Mutation (SNP) | VAF 59/65 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1323562284, COSV57398890; called by muse, mutect2, varscan2
- SLC16A13 | c.24dup p.D9Rfs*38 | Frame Shift Ins (INS) | VAF 5/42 reads (12%) | catalogued as rs766225805; called by pindel, varscan2
- SLC22A25 | c.224T>C p.I75T | Missense Mutation (SNP) | VAF 87/178 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV60596230; called by muse, mutect2, varscan2
- SLC25A14 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV99502676; called by muse, mutect2, varscan2
- SLC39A8 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63222327; called by mutect2, varscan2
- SLC6A5 | c.1433T>C p.L478S | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54227200; called by muse, mutect2, varscan2
- SMC4 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.762); catalogued as COSV58447870, COSV58447909; called by muse, mutect2, varscan2
- SSH3 | c.1907C>T p.S636F | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.28); catalogued as COSV57384928; called by muse, mutect2, varscan2
- SYNPO2L | c.2728dup p.R910Pfs*8 (on ENST00000394810 / NM_001114133.3; = p.R686Pfs*8 on NM_024875.5) | Frame Shift Ins (INS) | VAF 7/61 reads (11%) | catalogued as rs764821235; called by pindel, varscan2
- TAS2R1 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV101225876; called by muse, mutect2, varscan2
- TET1 | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 355/785 reads (45%) | catalogued as COSV101018959; called by mutect2, varscan2
- TEX15 | c.478T>C p.S160P (on ENST00000256246; = p.S543P on NM_001350162.2) | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV56347030; called by muse, mutect2, varscan2
- THBS2 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369355659; called by muse, mutect2, varscan2
- TLN2 | c.3760T>A p.S1254T | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.265); catalogued as COSV100170138; called by muse, mutect2
- TMEM164 | c.721C>T p.P241S (on ENST00000372068 / NM_032227.4; = p.P92S on NM_017698.2) | Missense Mutation (SNP) | VAF 262/1309 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99912138; called by mutect2, varscan2
- TMEM176B | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs779385517, COSV50241176; called by muse, mutect2, varscan2
- TPCN1 | c.1984C>T p.H662Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.308); catalogued as COSV59235555; called by muse, mutect2
- TTN | c.22133C>T p.A7378V (on ENST00000591111; = p.A6451V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/447 reads (26%) | PolyPhen benign (0.131); catalogued as rs201003628, COSV60086709; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR17 | c.776T>C p.I259T | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV54574694; called by muse, mutect2, varscan2
- ZBTB7B | c.463G>A p.D155N (on ENST00000292176; = p.D189N on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV52692764; called by muse, mutect2, varscan2
- ZNF518A | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.472); catalogued as COSV60151548; called by muse, mutect2, varscan2
- ZNF608 | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 435/676 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.168); catalogued as rs777103523, COSV60438062; called by muse, mutect2, varscan2
- ABHD3 | c.188A>G p.E63G | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0); called by mutect2, varscan2
- ALMS1 | c.6386G>A p.G2129D | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- FIP1L1 | c.1701dup p.S568Ifs*2 | Frame Shift Ins (INS) | VAF 148/360 reads (41%) | called by pindel, varscan2
- PAK6 | c.1838T>A p.L613H | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PPP2R5D | c.1136T>C p.M379T | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by mutect2, varscan2
- ZBTB41 | c.1263_1267del p.H422Vfs*5 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- ABCC1 | c.3129G>A p.L1043= | Silent (SNP) | VAF 141/284 reads (50%) | catalogued as COSV60686502; called by muse, varscan2
- AGAP6 | c.603C>A p.T201= (on ENST00000374056 / NM_001365867.1; = p.T224= on NM_001077665.2) | Silent (SNP) | VAF 18/411 reads (4%) | called by muse, mutect2
- ATP2A3 | c.2061C>T p.I687= | Silent (SNP) | VAF 36/585 reads (6%) | catalogued as rs766538399, COSV59228418; called by muse, mutect2
- ATP9B | c.2976G>A p.A992= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs774409845, COSV100302646; called by muse, varscan2
- ATRN | c.3483T>A p.I1161= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV53528145; called by muse, mutect2, varscan2
- CDKL5 | c.2970C>A p.T990= | Silent (SNP) | VAF 59/470 reads (13%) | catalogued as COSV66106567; called by muse, mutect2, varscan2
- CFAP52 | c.1182C>T p.N394= | Silent (SNP) | VAF 27/184 reads (15%) | catalogued as rs376283850; called by muse, mutect2, varscan2
- CLCN1 | c.2751T>G p.T917= | Silent (SNP) | VAF 68/162 reads (42%) | catalogued as COSV100578578; called by muse, mutect2, varscan2
- CRIM1 | c.1272C>T p.C424= | Silent (SNP) | VAF 25/416 reads (6%) | catalogued as rs1178328615, COSV99754563; called by muse, mutect2
- CSH1 | c.636G>A p.E212= | Silent (SNP) | VAF 36/486 reads (7%) | catalogued as COSV100298183, COSV100298414; called by muse, mutect2
- CYP19A1 | c.420C>T p.L140= | Silent (SNP) | VAF 72/579 reads (12%) | catalogued as COSV53058429, COSV99548172; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1080G>A p.K360= | Silent (SNP) | VAF 16/262 reads (6%) | catalogued as COSV100668878; called by muse, mutect2
- EFTUD2 | c.1092C>T p.S364= | Silent (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- FANCM | c.2619T>C p.G873= | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as COSV57501514; called by muse, mutect2, varscan2
- GRM3 | c.2175A>G p.T725= | Silent (SNP) | VAF 562/1142 reads (49%) | catalogued as COSV64472299; called by mutect2, varscan2
- ILF3 | c.1269G>A p.Q423= | Silent (SNP) | VAF 64/426 reads (15%) | catalogued as rs35968299, COSV51558129; called by mutect2, varscan2
- KLHDC2 | c.486G>A p.G162= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs1170061803, COSV53587374; called by muse, mutect2, varscan2
- KRT7 | c.885G>C p.G295= | Silent (SNP) | VAF 33/368 reads (9%) | called by mutect2, varscan2
- LRRC4C | c.45T>G p.G15= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV53426609; called by muse, mutect2, varscan2
- LRRN3 | c.723C>T p.I241= | Silent (SNP) | VAF 176/590 reads (30%) | catalogued as COSV57820405; called by mutect2, varscan2
- MAGEE1 | c.804G>A p.P268= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as rs782662647; called by muse, mutect2
- NUGGC | c.804G>A p.L268= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV100429830; called by muse, mutect2
- P4HB | c.456C>T p.S152= | Silent (SNP) | VAF 13/226 reads (6%) | catalogued as COSV100515932; called by muse, mutect2
- PALM2AKAP2 | c.564G>A p.K188= (on ENST00000259318 / NM_001136562.3; = p.K419= on NM_007203.5) | Silent (SNP) | VAF 8/241 reads (3%) | catalogued as COSV99395799; called by muse, mutect2
- PPL | c.1800C>T p.L600= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100630629; called by muse, mutect2
- RPLP0 | c.720T>C p.S240= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as COSV56108301; called by muse, mutect2, varscan2
- RSPH14 | c.771C>T p.F257= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as rs530778842, COSV53272080; called by muse, mutect2, varscan2
- SLC16A14 | c.1107C>A p.I369= | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as COSV54616855, COSV54618721; called by muse, mutect2, varscan2
- SPAG1 | c.2698C>T p.L900= | Silent (SNP) | VAF 50/59 reads (85%) | catalogued as COSV52560142; called by muse, mutect2, varscan2
- TACR3 | c.133C>T p.L45= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV100511046; called by muse, varscan2
- THNSL2 | c.855G>A p.V285= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV100147695; called by muse, mutect2, varscan2
- TPR | c.2046C>T p.Y682= | Silent (SNP) | VAF 7/138 reads (5%) | catalogued as COSV66605674; called by muse, mutect2
- TTLL9 | c.1248C>T p.C416= | Silent (SNP) | VAF 71/497 reads (14%) | catalogued as rs376499277; called by muse, varscan2
- TUBG2 | c.777G>C p.S259= | Silent (SNP) | VAF 31/270 reads (11%) | catalogued as COSV52217788; called by muse, mutect2, varscan2
- WSB2 | c.1170A>G p.P390= | Silent (SNP) | VAF 269/475 reads (57%) | catalogued as COSV57477736; called by muse, mutect2, varscan2
- YTHDF1 | c.843G>A p.P281= | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as rs542852740; called by muse, varscan2
- ZNF697 | c.1464G>A p.T488= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as rs745907170, COSV70284141; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845537 T>C | 5'Flank (SNP) | VAF 42/363 reads (12%) | catalogued as rs776677269; called by muse, mutect2
- CLLU1 | n.879T>G | RNA (SNP) | VAF 5/19 reads (26%) | catalogued as COSV65903104; called by muse, mutect2, varscan2
- MIR376C | n.5G>C | RNA (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- MIR519E | n.25G>A | RNA (SNP) | VAF 58/217 reads (27%) | catalogued as rs1199021002; called by muse, varscan2
- SPTBN1 | c.148+32253C>T | Intron (SNP) | VAF 13/300 reads (4%) | catalogued as rs940361537, COSV100443478; called by muse, mutect2
- TBC1D32 | c.2571-9380G>C | Intron (SNP) | VAF 55/94 reads (59%) | catalogued as COSV99251374; called by muse, mutect2, varscan2
- XIRP2 | c.*419C>A | 3'UTR (SNP) | VAF 15/81 reads (19%) | catalogued as COSV54702659; called by muse, mutect2, varscan2
